Somatic mutation profile of tumor specimen C3L-01287-03 (aliquot CPT0079420012) from CPTAC case C3L-01287, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 60.4 years (22,045 days).
Specimen C3L-01287-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4482f2ae-4d36-484a-b034-891fcfefd2c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01287-31 (Blood Derived Normal), aliquot CPT0080130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7226250d-5ddd-490a-8a90-a8b7d1558e4f

The open-access MAF lists 54 somatic variants for this specimen: 32 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 17, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, Splice Site 2, Splice Region 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as COSV63977338; called by muse, mutect2
- CACNA1H | c.5384G>C p.G1795A | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52357665; called by muse, mutect2, varscan2
- CDH16 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751244459, COSV100233742; called by muse, mutect2, varscan2
- CDH23 | c.8674C>T p.R2892W | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1468886300, COSV56482903, COSV99819181; called by muse, mutect2, varscan2
- DBF4B | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as rs867067834; called by muse, mutect2
- EIF2D | c.948+2T>C p.X316_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as rs1553411032; called by muse, mutect2, varscan2
- FAHD2A | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 20/321 reads (6%) | catalogued as rs773693722; called by muse, mutect2
- FKBP10 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as rs782380098; called by muse, mutect2
- JCAD | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64759879; called by muse, mutect2
- PXDNL | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62477807; called by muse, mutect2, varscan2
- TRIM31 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs1388640225; called by muse, mutect2
- TUBGCP2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs761200870; called by muse, mutect2, varscan2
- USP6NL | c.2483T>A p.L828Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs562437933; called by muse, mutect2, varscan2
- ADCY9 | c.3617T>C p.I1206T | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AHNAK | c.1070G>A p.S357N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ALKBH7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL14A1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- DCBLD1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FAM149B1 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- GABBR2 | c.2197_2205del p.T733_T735del | In Frame Del (DEL) | VAF 59/271 reads (22%) | called by mutect2, pindel, varscan2
- HLA-DMB | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.2211A>G p.K737= | Splice Region (SNP) | VAF 30/325 reads (9%) | called by muse, mutect2
- ILF2 | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- KARS1 | c.1547_1551+1del p.X516_splice | Splice Site (DEL) | VAF 53/353 reads (15%) | called by pindel, varscan2*
- MED1 | c.1400_1401dup p.D468Wfs*9 | Frame Shift Ins (INS) | VAF 38/286 reads (13%) | called by mutect2, pindel, varscan2
- RC3H1 | c.2490del p.D831Mfs*10 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- RNF17 | c.1620C>A p.H540Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2
- RYR2 | c.8923T>C p.F2975L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SPEM2 | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM270 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VHL | c.420_442del p.N141Cfs*25 | Frame Shift Del (DEL) | VAF 60/276 reads (22%) | called by mutect2, pindel
- ZMYM5 | c.621T>A p.S207R | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- CACNA1H | c.5385C>T p.G1795= | Silent (SNP) | VAF 25/154 reads (16%) | catalogued as rs777171977; called by muse, mutect2, varscan2
- COG5 | c.2100A>T p.S700= (on ENST00000347053 / NM_001379512.1; = p.S721= on NM_006348.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 63/344 reads (18%) | called by muse, mutect2, varscan2
- CPA6 | c.60C>T p.L20= | Silent (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- HLA-DMB | c.93G>A p.L31= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- KDM2B | c.1563G>A p.V521= | Silent (SNP) | VAF 44/325 reads (14%) | called by muse, mutect2, varscan2
- KDM5A | c.2100C>G p.L700= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- MBD5 | c.3753A>G p.P1251= | Silent (SNP) | VAF 59/289 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.7020C>T p.T2340= | Silent (SNP) | VAF 30/318 reads (9%) | called by muse, mutect2
- NOD2 | c.381G>A p.S127= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs535978538; called by muse, mutect2, varscan2
- NOTCH2 | c.6909C>T p.P2303= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1311553574; called by muse, mutect2, varscan2
- PCDHB3 | c.1347C>T p.P449= | Silent (SNP) | VAF 112/592 reads (19%) | catalogued as rs782743177, COSV50569020, COSV50574942; called by muse, varscan2
- PTPRZ1 | c.1605A>C p.S535= | Silent (SNP) | VAF 32/201 reads (16%) | called by muse, mutect2, varscan2
- RIN1 | c.390C>T p.S130= | Silent (SNP) | VAF 73/282 reads (26%) | called by muse, mutect2, varscan2
- STYXL2 | c.1302G>T p.L434= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- TNNT3 | c.654G>A p.L218= (on ENST00000397301 / NM_001367846.1; = p.L207= on NM_006757.4) | Silent (SNP) | VAF 20/541 reads (4%) | called by muse, mutect2
- TRIM27 | c.1098C>T p.F366= | Silent (SNP) | VAF 49/210 reads (23%) | catalogued as rs1252217990, COSV65874203; called by muse, mutect2, varscan2
- XKR4 | c.483G>A p.V161= | Silent (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- FANCL | c.775+21A>G | Intron (SNP) | VAF 32/190 reads (17%) | called by mutect2, varscan2
- LRP5L | n.298C>T | RNA (SNP) | VAF 77/330 reads (23%) | called by muse, mutect2, varscan2
- MBD2 | c.542+1616C>A | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- SREBF2 | c.2739-38A>G | Intron (SNP) | VAF 67/260 reads (26%) | catalogued as rs746778890; called by muse, mutect2, varscan2
- ZFPL1 | chr11:65090494 T>G | 3'Flank (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
